Gene-level copy-number profile of tumor specimen TCGA-CD-A487-01A from TCGA case TCGA-CD-A487, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 51.2 years (18,694 days).
Specimen TCGA-CD-A487-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.5bda42ff-037d-417f-a71a-65ec8d363077.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CD-A487-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b473b21f-f37b-468c-834d-18ac46625c8b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 1,589; copy number 2: 32,294; copy number 3: 5,540; copy number 4: 15,555; copy number 5: 3,390; copy number 6: 1,340; copy number 7: 63; copy number 8: 35; copy number 23: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CD-A487-01A-21D-A24C-01): tumor purity 0.42, ploidy 2.49, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:175,059,361–175,115,242, 2 genes: EEF1B2P8, NAALADL2-AS3.
- chr4:91,108,023–91,112,790, 1 gene: AC004054.1.
- chr12:24,223,233–24,260,056, 1 gene (within-gene range 0–2): SOX5-AS1.
- chr20:14,933,843–15,280,873, 4 genes: AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,830 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:234,646,289–234,980,804, 12 genes, copy number 8 (within-gene range 4–8): AL160408.1, AL160408.4, AL160408.3, AL160408.6, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3.
- chr3:93,843,764–110,727,121, 215 genes, copy number 5 (broad region; genes not listed).
- chr3:115,802,363–117,139,389, 1 gene, copy number 5 (within-gene range 2–5): LSAMP.
- chr3:116,360,024–136,205,915, 409 genes, copy number 5 (broad region; genes not listed).
- chr3:136,752,630–175,810,548, 577 genes, copy number 5–6 (within-gene range 0–6) (broad region; genes not listed).
- chr3:175,473,919–198,222,513, 492 genes, copy number 6–8 (broad region; genes not listed).
- chr5:160,008,445–160,487,426, 17 genes, copy number 5: Y_RNA, TTC1, AC068657.1, PWWP2A, FABP6, FABP6-AS1, AC112191.1, CCNJL, AC112191.2, AC112191.3, C1QTNF2, ZBED8, SLU7, PTTG1, MIR3142HG, MIR3142, MIR146A.
- chr10:38,094,368–38,360,098, 1 gene, copy number 5 (within-gene range 4–5): AL117339.4.
- chr10:38,161,570–75,182,123, 607 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr19:29,811,991–29,841,818, 2 genes, copy number 23: CCNE1, AC008798.2.
- chr19:45,589,764–55,778,900, 747 genes, copy number 5–7 (broad region; genes not listed).
- chr20:87,250–13,996,443, 281 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:15,552,157–64,313,132, 1,162 genes, copy number 5 (broad region; genes not listed).
- chr22:15,290,718–21,551,461, 306 genes, copy number 6 (broad region; genes not listed).
- chr22:21,555,138–21,555,457, 1 gene, copy number 6: Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 1,092. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
